Somatic mutation profile of tumor specimen TCGA-FP-A4BF-01A (aliquot TCGA-FP-A4BF-01A-12D-A24D-08) from TCGA case TCGA-FP-A4BF, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.5 years (25,030 days).
Specimen TCGA-FP-A4BF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0e69e08-4f0b-42c2-a600-da36bae8cf32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-A4BF-10A (Blood Derived Normal), aliquot TCGA-FP-A4BF-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8337b490-0b69-4aef-8089-6cfd75badaee

The open-access MAF lists 106 somatic variants for this specimen: 83 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 21, Nonsense Mutation 4, Splice Site 2, Splice Region 2, Frame Shift Del 2, RNA 1, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKH | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs28939080, CM011274, COSV52476395; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA13 | c.400A>G p.N134D | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.408); catalogued as COSV70025610; called by muse, mutect2, varscan2
- ABCD2 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs751049564, COSV58049246; called by muse, mutect2, varscan2
- AIP | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as rs746414951, COSV54159702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.3032G>A p.R1011H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1563808779, COSV52144383; called by muse, mutect2, varscan2
- APCDD1L | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.142); catalogued as COSV64485254; called by muse, mutect2
- BEX3 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV100244374, COSV55420986; called by muse, mutect2, varscan2
- C1orf56 | c.1005+3_1005+6del p.X335_splice | Splice Site (DEL) | VAF 37/98 reads (38%) | catalogued as rs1320396834; called by mutect2, pindel, varscan2
- CDH18 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776963132, COSV56899350; called by mutect2, varscan2
- CENPF | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs199800194; called by muse, mutect2, varscan2
- CHRNA4 | c.794T>C p.F265S | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs910734867, COSV64718407; called by muse, mutect2, varscan2
- CNNM4 | c.1680A>G p.T560= | Splice Region (SNP) | VAF 14/100 reads (14%) | catalogued as COSV65660172; called by muse, mutect2, varscan2
- CNTRL | c.6731G>A p.R2244Q | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.213); catalogued as rs764424296, COSV53042807; called by muse, mutect2, varscan2
- CPXM1 | c.2032T>C p.Y678H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66044527; called by muse, mutect2, varscan2
- CYP2A6 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 141/311 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as rs185545560; called by muse, mutect2, varscan2
- DCAF12L1 | c.530A>T p.Y177F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64421136; called by muse, mutect2, varscan2
- DENND4C | c.4151A>T p.H1384L (on ENST00000434457 / NM_001330640.2; = p.H1335L on NM_017925.7) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.343); catalogued as rs754928464, COSV63008277; called by mutect2, varscan2
- DHX57 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1290963826, COSV54882222, COSV54891848; called by muse, mutect2, varscan2
- DHX9 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62358121; called by muse, mutect2, varscan2
- DKK1 | c.527C>A p.S176* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs774087271, COSV64759908; called by muse, varscan2
- DSN1 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 44/194 reads (23%) | catalogued as COSV65518459; called by muse, mutect2, varscan2
- EFR3A | c.2199A>T p.K733N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV54452921; called by muse, mutect2
- ERMP1 | c.2359T>G p.S787A | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV53036073; called by muse, mutect2, varscan2
- FAT3 | c.6108G>T p.Q2036H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as COSV53072860; called by muse, mutect2, varscan2
- GLIPR2 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1316789057, COSV65028854; called by muse, mutect2, varscan2
- GP1BA | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759216138, COSV56698559, COSV56699876; called by muse, mutect2, varscan2
- GPR101 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53237271; called by muse, mutect2, varscan2
- GTF2IRD1 | c.37A>G p.N13D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.394); catalogued as COSV56084205; called by muse, mutect2, varscan2
- HCN1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1333872397, COSV100298381, COSV57492101, COSV57537055; called by muse, mutect2
- HOXA6 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 212/391 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56071959; called by muse, mutect2, varscan2
- HOXA7 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 165/300 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1477746824, COSV54216617; called by muse, mutect2, varscan2
- HSP90AA1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV99355485; called by muse, mutect2, varscan2
- IDH3A | c.1051T>A p.C351S | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV51903141; called by muse, mutect2, varscan2
- IFI16 | c.478T>A p.S160T | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.264); catalogued as COSV55530578; called by muse, mutect2
- IQGAP2 | c.4261C>T p.L1421F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57167512; called by muse, mutect2, varscan2
- KDM6A | c.185T>C p.F62S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV65036889; called by muse, mutect2, varscan2
- KIAA1217 | c.3246+2T>C p.X1082_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as COSV56811993; called by muse, mutect2, varscan2
- LILRB1 | c.982G>A p.G328R (on ENST00000427581; = p.G292R on NM_006669.6) | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.486); catalogued as rs1183360601, COSV61115734; called by muse, mutect2, varscan2
- LPCAT2 | c.1074T>A p.D358E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV50894124; called by muse, mutect2, varscan2
- LRPPRC | c.1747T>C p.Y583H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53233661; called by mutect2, varscan2
- LRRK2 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54142603; called by muse, mutect2, varscan2
- MAGEB6B | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1373548278; called by muse, mutect2, varscan2
- MKNK2 | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51730277; called by muse, mutect2, varscan2
- MMP16 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.17); catalogued as COSV54149653; called by muse, mutect2, varscan2
- MPO | c.1837A>C p.T613P | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV51856556; called by muse, mutect2, varscan2
- MTMR1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV64892179; called by muse, mutect2, varscan2
- MUC16 | c.30607T>G p.F10203V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67442537; called by muse, mutect2, varscan2
- NALCN | c.4819C>T p.R1607W | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs866709006, COSV51915914; called by muse, mutect2, varscan2
- NBEA | c.8705G>A p.G2902E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV59758134; called by muse, mutect2, varscan2
- PCOLCE2 | c.423C>A p.F141L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV55997328; called by muse, mutect2, varscan2
- PKHD1 | c.8647A>G p.I2883V | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV61859265; called by muse, mutect2, varscan2
- PLXNC1 | c.1513A>C p.K505Q | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51569011; called by muse, mutect2, varscan2
- POMGNT1 | c.1500C>A p.H500Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV64339288; called by muse, mutect2, varscan2
- POU3F3 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV63721124; called by muse, mutect2, varscan2
- PPIL4 | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV53566085; called by muse, mutect2, varscan2
- PRAMEF20 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as rs1200392559; called by muse, mutect2, varscan2
- PTPRM | c.4183C>T p.R1395C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753091710, COSV59842875; called by muse, mutect2, varscan2
- PYY | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs371634156, COSV63969759; called by muse, mutect2, varscan2
- RPS27A | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs569250342, COSV55050093; called by muse, mutect2
- RYR2 | c.6686T>C p.L2229P | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63658932; called by muse, mutect2, varscan2
- SACS | c.10784T>C p.L3595P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV66533520; called by mutect2, varscan2
- SDK1 | c.5844C>A p.D1948E | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as COSV67355578; called by muse, mutect2
- SEL1L | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV60918850; called by muse, mutect2, varscan2
- SLCO1B1 | c.1749A>G p.G583= | Splice Region (SNP) | VAF 43/91 reads (47%) | catalogued as COSV57006766; called by muse, mutect2, varscan2
- SNRPN | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57593843, COSV57596019; called by muse, mutect2, varscan2
- SPATA31D1 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.237); catalogued as COSV100783021; called by muse, mutect2
- SPSB3 | c.132C>A p.S44R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51904531; called by muse, mutect2, varscan2
- SPTBN4 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs755189410, COSV58943118; called by muse, mutect2, varscan2
- TAFA2 | c.285G>C p.W95C | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69171744; called by muse, mutect2
- TENM2 | c.7955C>A p.S2652Y (on ENST00000518659 / NM_001122679.2; = p.S2413Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV69122328; called by muse, mutect2
- TIAM1 | c.4432G>A p.G1478R | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs772268816, COSV54536505; called by muse, mutect2, varscan2
- TMEM177 | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 33/200 reads (17%) | catalogued as COSV55608093; called by muse, mutect2, varscan2
- TRIM5 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.917); catalogued as rs370971495, COSV59898474; called by muse, mutect2, varscan2
- UBA7 | c.1400T>C p.V467A | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV61091222; called by muse, mutect2, varscan2
- USP37 | c.2906C>T p.T969M | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs775995888, COSV50285342; called by muse, mutect2, varscan2
- XRN2 | c.1309A>C p.I437L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV65867910; called by muse, mutect2, varscan2
- ZNF329 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.166); catalogued as COSV63771609; called by muse, mutect2, varscan2
- ZWINT | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.046); catalogued as COSV59184778; called by muse, mutect2, varscan2
- AC013477.1 | c.2412del p.I804Mfs*17 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- CABCOCO1 | c.558_569dup p.I187_K190dup | In Frame Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- MUC16 | c.20153T>C p.I6718T | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SUOX | c.556_571del p.L186Sfs*13 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | called by mutect2, pindel
- ABCA7 | c.3123C>T p.R1041= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1280994184, COSV54023550, COSV99564988; called by muse, mutect2, varscan2
- ADAT3 | c.861C>T p.D287= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs372168072; called by muse, mutect2, varscan2
- ANKRD11 | c.324C>T p.G108= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as COSV56354176; called by muse, mutect2, varscan2
- BIRC6 | c.7125G>A p.V2375= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV70195222; called by muse, mutect2, varscan2
- CBWD1 | c.60T>A p.P20= | Silent (SNP) | VAF 22/304 reads (7%) | catalogued as COSV58697903; called by muse, mutect2
- CD109 | c.630G>T p.V210= | Silent (SNP) | VAF 19/154 reads (12%) | catalogued as COSV54644923; called by muse, varscan2
- COL6A3 | c.3831C>T p.S1277= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs114110705, COSV55078825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESRRB | c.1236C>T p.S412= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs754937579, COSV55058179; called by muse, mutect2, varscan2
- FGFR2 | c.2106G>A p.S702= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs794727163, COSV60639108; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GPANK1 | c.513G>A p.G171= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs753558725, COSV63263567; called by muse, mutect2, varscan2
- GRM1 | c.2251C>T p.L751= | Silent (SNP) | VAF 72/127 reads (57%) | catalogued as COSV51108138, COSV99267784; called by muse, mutect2, varscan2
- LAMA1 | c.3288G>A p.G1096= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV67531559; called by muse, mutect2
- LRRC30 | c.528G>A p.A176= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as rs754328853, COSV67301257, COSV67302230; called by muse, mutect2, varscan2
- MMP2 | c.126C>T p.A42= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV54598904; called by muse, mutect2, varscan2
- N4BP2 | c.4401A>G p.K1467= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV54698677; called by muse, mutect2, varscan2
- RETNLB | c.9G>A p.P3= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs748896437, COSV55465084; called by mutect2, varscan2
- SERPINB8 | c.684C>T p.V228= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV54638982; called by muse, mutect2, varscan2
- SLC18A2 | c.714C>T p.F238= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs549412168, COSV53688321; called by muse, mutect2, varscan2
- SLC8A1 | c.2322C>T p.F774= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs770499303, COSV60470065, COSV60497665; called by muse, mutect2
- STAC | c.24C>T p.R8= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV56206264; called by muse, mutect2
- TBXT | c.366C>T p.C122= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs201970663, COSV51615944; called by muse, mutect2, varscan2
- AQP1 | c.*327G>A | 3'UTR (SNP) | VAF 15/30 reads (50%) | catalogued as rs773654140, COSV100311035, COSV61268552; called by muse, varscan2
- DCHS2 | n.3249G>A | RNA (SNP) | VAF 17/143 reads (12%) | catalogued as rs752655581, COSV59717812; called by muse, mutect2, varscan2
